Gene-level copy-number profile of tumor specimen TCGA-34-2609-01A from TCGA case TCGA-34-2609, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 81.8 years (29,871 days).
Specimen TCGA-34-2609-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b8f0b240-a0df-4cd3-85b4-0b6fa3068e16.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-2609-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b1053711-505e-4b9b-ad6b-f466e5b9a750

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,904; copy number 2: 7,157; copy number 3: 20,540; copy number 4: 14,291; copy number 5: 6,291; copy number 6: 4,524; copy number 7: 2,476; copy number 8: 1,314; copy number 9: 449; copy number 10: 423; copy number 12: 8; copy number 13: 320; copy number 14: 9; copy number 16: 28; copy number 17: 1; copy number 23: 18; copy number 29: 11; copy number 30: 12; copy number 58: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-2609-01A-01D-0844-01): tumor purity 0.32, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,087 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:113,747,033–169,038,416, 937 genes, copy number 7–8 (broad region; genes not listed).
- chr4:53,377,839–82,044,244, 445 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr4:134,759,399–136,553,739, 19 genes, copy number 8: AC093722.1, AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, U6, KRT18P54, TARS2P1, AC105362.1, LINC00613, RNU1-89P, AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3, AC093875.1.
- chr5:58,198–45,895,970, 710 genes, copy number 7–8 (broad region; genes not listed).
- chr6:159,669,069–170,738,536, 197 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:150,584–264,703, 11 genes, copy number 10: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2.
- chr8:33,039,523–38,601,200, 104 genes, copy number 9–58 (broad region; genes not listed).
- chr8:41,653,220–41,896,762, 1 gene, copy number 10 (within-gene range 4–10): ANK1.
- chr8:41,803,349–53,390,872, 162 genes, copy number 7–10 (broad region; genes not listed).
- chr8:53,394,215–53,394,795, 1 gene, copy number 7: AC131902.2.
- chr8:61,500,556–104,256,094, 701 genes, copy number 7–8 (within-gene range 1–8) (broad region; genes not listed).
- chr8:104,330,324–134,390,487, 353 genes, copy number 7 (broad region; genes not listed).
- chr10:80,940,665–81,137,335, 2 genes, copy number 9: WARS2P1, RPA2P2.
- chr10:120,925,547–133,761,125, 230 genes, copy number 8 (broad region; genes not listed).
- chr12:84,671,598–85,036,277, 4 genes, copy number 8: AC093027.1, SLC6A15, AC128657.1, TSPAN19.
- chr14:18,333,726–20,122,199, 92 genes, copy number 8 (broad region; genes not listed).
- chr16:24,333,415–26,607,396, 35 genes, copy number 9–12 (within-gene range 6–12): AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HSPE1P16, AC009158.1, AC130464.1, AC002331.1.
- chr17:52,862,121–53,106,358, 3 genes, copy number 12: LINC02089, LINC02876, MTCO1P40.
- chr17:56,368,063–56,595,611, 4 genes, copy number 14: AC006600.1, AC006600.2, RPL39P33, NOG.
- chr17:60,392,429–71,871,750, 281 genes, copy number 7–13 (broad region; genes not listed).
- chr17:72,627,231–74,154,212, 29 genes, copy number 8–30: RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, AC137735.3, AC137735.2, LINC02074.
- chr20:22,054,074–22,343,930, 5 genes, copy number 14: LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1.
- chr20:30,214,765–52,890,386, 609 genes, copy number 10–13 (broad region; genes not listed).
- chr22:29,387,909–33,058,381, 152 genes, copy number 7–9 (within-gene range 4–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 925. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
